Surgical pathology report (de-identified scan), TCGA case TCGA-B1-A47M, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B1-A47M-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Left renal cell carcinoma.

PROCEDURE: Nephrectomy, complete.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION THERAPY: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

**SPECIMEN(S) RECEIVED:**

1. left kidney

ADDENDUM

This is an addendum to report the results of Immunostaining:

The neoplastic cells are positive for racemase, CK7, CA9 (focal) and CD10 (focal). Overall, these immunohistochemical staining profile is consistent with a papillary renal cell carcinoma with clear cell features.

Our final diagnosis remains unchanged.

> 50% clear cell features, per RSS.
9/6/12 lw

FINAL DIAGNOSIS:**PART 1:****KIDNEY, LEFT, RADICAL NEPHRECTOMY-**

- A. PAPILLARY RENAL CELL CARCINOMA, TYPE 2 WITH CLEAR CELL FEATURES. (See Comment).
- B. FUHRMAN GRADE 3/4.
- C. TUMOR MEASURES 4.5 X 4.0 X 3.5 CM.
- D. TUMOR INVADIES THE PERI-RENAL ADIPOSE TISSUE.
- E. TUMOR DOES NOT INVOLVE THE GEROTA'S FASCIA.
- F. ALL MARGINS ARE NEGATIVE
- G. TUMOR TO CLOSEST INKED PARENCHYMAL MARGIN IS LESS THAN 0.1 CM.
- H. NO VASCULAR INVASION IS IDENTIFIED.

I. PATHOLOGIC STAGE pT3a Nx Mx.

COMMENT:

Immunostains are pending to further characterize this tumor, and the results will be reported in an addendum.

ICA-0-3

carcinoma, papillary renal cell
8260/3

Site: Kidney, NOS C64.9

lw
9/27/12

Source: NCI Genomic Data Commons file 74ab53b9-3e2c-4381-aafc-fb09da735436 (TCGA-B1-A47M.462D07AA-748E-4758-A432-989274226745.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).